Gene-level copy-number profile of specimen HCM-CSHL-0238-C18-85A from HCMI case HCM-CSHL-0238-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.8 years (26,209 days).
Specimen HCM-CSHL-0238-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d21cc25-67f2-4fa0-ad91-1e97f0499ab3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0238-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/d120634b-3819-4441-bde7-4c6c63c7df1e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 562; copy number 2: 11,142; copy number 3: 39,659; copy number 4: 2,605; copy number 5: 2,164; copy number 6: 1,355; copy number 7: 281; copy number 8: 1,139.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,420 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 8: CFHR3.
- chr13:105,459,055–106,942,561, 21 genes, copy number 7: DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, RNA5SP38, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL162574.2, PPIAP24, AL162574.1, AL162574.3.
- chr20:87,250–16,053,197, 284 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 8 (within-gene range 6–8): MACROD2-AS1.
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 7–8 (broad region; genes not listed).
- chr21:13,609,858–13,654,356, 4 genes, copy number 7: POTED, RNU6-286P, MIR3118-1, AL050303.2.

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
